TCGA case TCGA-3B-A9I3 — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Myomatous Neoplasms; Primary site: Retroperitoneum and peritoneum; Tissue source site: Moffitt Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a93fd240-59c1-4527-854e-dfd042222fcf

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 62 years; Vital status: Alive.

Diagnoses (2)
1. Leiomyosarcoma, NOS (the primary disease): ICD-O-3 morphology code: 8890/3; ICD-10 code: C48.0; Tissue or organ of origin: Retroperitoneum; Site of resection or biopsy: Retroperitoneum; Classification of tumor: primary; Age at diagnosis: 62.9 years (22,985 days); Year of diagnosis: 2012; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Tumor focality: Unifocal.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 12; Tumor width measurement: 7.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor length measurement: 9; Tumor width measurement: 4.
   Pathology details: Consistent pathology review: Yes; Margin status: Involved.
2. Subsequent primary of the lymph nodes of axilla or arm (histology not recorded by GDC). Age at diagnosis: 63.2 years (23,072 days); Days to diagnosis: 87 days; Prior treatment: Yes; Tumor focality: Multifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 0.7; Tumor length measurement: 3; Tumor width measurement: 1.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor depth measurement: 1.2; Tumor length measurement: 2; Tumor width measurement: 1.6.
   Recorded as not given: Pharmaceutical Therapy, NOS, for initial diagnosis.

Follow-up (3 entries)
- Days to follow up: 87 days; Discontiguous lesion count: 2.
- Days to follow up: 626 days (1.7 years); Disease response: Tumor Free.
- Days to follow up: 808 days (2.2 years); Disease response: Tumor Free.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-3B-A9I3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 90 mg.
  Slide TCGA-3B-A9I3-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 75; Percent normal cells: 15; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-3B-A9I3-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-3B-A9I3-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; New tumor event diagnosis indicator: Yes.
- Primary pathology: Histologic diagnosis: Leiomyosarcoma (LMS); Histologic subtype: Conventional leiomyosarcoma; Leiomyo major vessel involvement: No Major Vessel Involvement; Margin status: Positive; Disease multifocal indicator: No; Locoregional recurrence indicator: No; Metastatic disease confirmed: No; Contiguous organ invaded: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Retroperitoneum/Upper abdominal - Retroperitoneum.
- Primary pathology, Tumor sizes, Tumor size: Lesion radiologic width: 7; Lesion pathologic length: 9; Lesion pathologic width: 4.
- New tumor event: New tumor event type: New Primary Tumor; New tumor event site other: Axillary Lymph Node; New tumor event surgery: Yes; Days from index date to new tumor event surgery: 242; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: No; New tumor event residual tumor: RX; Disease multifocal indicator: Yes; Discontinuous lesions count: 2.
- New tumor event, New tumor event tumor sizes, New tumor event tumor size: New tumor event lesion radiologic length: 2; New tumor event lesion pathologic length: 3; New tumor event lesion pathologic width: 1.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 808 days; disease-specific survival: no event (censored), 808 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 87 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-3B-A9I3-01A-11D-A38Y-01): tumor purity 0.4, ploidy 1.62, whole-genome doublings 0.
